Gene-level copy-number profile of tumor specimen TCGA-A4-A5Y0-01A from TCGA case TCGA-A4-A5Y0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.2 years (22,341 days).
Specimen TCGA-A4-A5Y0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.61c8ed3e-ce75-4c23-849c-61aab9e5f9fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A4-A5Y0-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/73148aad-3994-40ab-a0a5-0612252e26f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,667; copy number 2: 53,400; copy number 3: 3,047; copy number 4: 305; copy number 6: 47; copy number 7: 272; copy number 8: 64; copy number 9: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A4-A5Y0-01A-11D-A31W-01): tumor purity 0.95, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 399 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:27,070,472–28,450,184, 55 genes, copy number 7: OST4, EMILIN1, KHK, CGREF1, ABHD1, PREB, PRR30, TCF23, AC013403.1, SLC5A6, ATRAID, CAD, SLC30A3, DNAJC5G, TRIM54, UCN, MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2, CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS, BABAM2, MYG1P1, MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1.
- chr2:28,460,256–28,460,361, 1 gene, copy number 7: SNRPGP7.
- chr2:33,274,465–33,285,887, 2 genes, copy number 6: AC019127.1, RNA5SP91.
- chr2:163,152,251–163,289,096, 2 genes, copy number 6: RPL7P61, RNU6-627P.
- chr2:165,747,588–167,259,753, 15 genes, copy number 6 (within-gene range 2–6): GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1.
- chr2:167,631,480–169,701,708, 28 genes, copy number 6: RNU7-148P, CTAGE14P, B3GALT1-AS1, B3GALT1, STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2, ABCB11, DHRS9, AC007556.1, UBE2V1P6, LRP2, BBS5, AC093899.2, KLHL41, FASTKD1, AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2.
- chr2:171,317,405–189,012,746, 273 genes, copy number 7–9 (broad region; genes not listed).
- chr2:196,967,017–197,786,762, 22 genes, copy number 8 (within-gene range 4–8): ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL.
- chr2:198,882,573–199,071,791, 1 gene, copy number 8 (within-gene range 4–8): AC020718.1.

Autosomal genes at a single copy (total copy number 1): 2,667. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
